Gene-level copy-number profile of tumor specimen TCGA-PZ-A5RE-01A from TCGA case TCGA-PZ-A5RE, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 44.5 years (16,255 days).
Specimen TCGA-PZ-A5RE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.d5b2bde9-315b-471f-bfc9-ae0b99896e91.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-PZ-A5RE-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aad4d4f4-f549-470f-ade8-e99b04bb215c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 92; copy number 1: 8,789; copy number 2: 47,836; copy number 3: 2,610; copy number 4: 373; copy number 5: 24; copy number 6: 14; copy number 7: 30; copy number 10: 37; copy number 15: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-PZ-A5RE-01A-11D-A32M-01): tumor purity 0.51, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 92 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:197,569–266,398, 2 genes (within-gene range 0–2): AC079779.1, SH3YL1.
- chr9:20,331,446–26,118,408, 90 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 114 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:97,963,658–99,632,408, 46 genes, copy number 10–15: MIR5692A1, MIR5692C2, OR7E38P, AC004967.2, AC004967.1, OCM2, RN7SL478P, LMTK2, BHLHA15, TECPR1, BRI3, BAIAP2L1, AC093799.1, RPS3AP26, PPIAP82, AC074121.1, NPTX2, RNU6-393P, TMEM130, TRRAP, MIR3609, AC004893.2, RNF14P3, SMURF1, AC004893.1, KPNA7, MYH16, AC004834.1, AC004922.1, ARPC1A, ARPC1B, PDAP1, BUD31, PTCD1, ATP5MF-PTCD1, CPSF4, AC073063.1, ATP5MF, ZNF789, ZNF394, ZKSCAN5, FAM200A, ZNF655, AC005020.2, TMEM225B, ZSCAN25.
- chr18:894,435–1,310,018, 8 genes, copy number 6 (within-gene range 4–6): AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3.
- chr18:5,954,706–6,415,237, 1 gene, copy number 7 (within-gene range 4–7): L3MBTL4.
- chr18:6,256,747–8,832,778, 46 genes, copy number 5–7: L3MBTL4-AS1, MIR4317, AP005060.1, RNU6-349P, RPL6P27, AP005202.2, LINC01387, AP005202.1, RN7SL282P, AP005205.1, AP005205.3, AP005205.2, ARHGAP28, AP005210.2, AP005210.1, LINC00668, SCML2P1, RNU6-916P, LAMA1, AP002409.1, AP005062.1, SLC25A51P2, LRRC30, AP005270.1, AP001095.1, PTPRM, AP000897.2, AP000897.1, U3, AP005900.1, AC006566.2, AC006566.1, AP001094.3, AP001094.2, AP001094.1, COP1P1, RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1.
- chr18:10,661,933–11,149,569, 6 genes, copy number 6 (within-gene range 4–6): AP001180.1, PIEZO2, AP001180.4, KIAA0895LP1, MIR6788, AP005120.1.
- chr19:31,787,148–32,244,083, 7 genes, copy number 5: RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, AC074139.1, RNA5SP472.

Autosomal genes at a single copy (total copy number 1): 8,789. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
